MMRF case MMRF_1460 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6a6c45d8-4196-42fd-a9c8-2f9f3879164e

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 85 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 85.6 years (31,277 days); ISS stage: III; Days to last known disease status: 257 days; Days to last follow up: 257 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 258 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 166 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 3): M Protein 2.65 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 58.8 mg/dL; Immunoglobulin G 18.2 g/L; Immunoglobulin A 2.26 g/L; Immunoglobulin M 1.24 g/L; Beta 2 Microglobulin 5.86 µg/mL; Lactate Dehydrogenase 1.92 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 15 mmol/L; Calcium 2.23 mmol/L; Albumin 34 g/L; Glucose 7.76 mmol/L.
- Day 93 (ECOG 3): M Protein 0.33 g/dL; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 6.1 g/dL; Glucose 7.1 mmol/L.
- Day 172 (ECOG 4): M Protein 0.3 g/dL; Lactate Dehydrogenase 3.35 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 168 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.4 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 13.9 mmol/L.
- Day 257 (ECOG 4): M Protein 0.3 g/dL; Hemoglobin 6.51 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 177 µmol/L; Blood Urea Nitrogen 13.6 mmol/L; Calcium 2.28 mmol/L; Albumin 33 g/L; Total Protein 6 g/dL; Glucose 6.16 mmol/L.

Other clinical attributes
- Day 1: Weight: 79 kg; Height: 180 cm.

Biospecimens (2 samples)
- Sample MMRF_1460_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1460_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
